Surgical pathology report (de-identified scan), TCGA case TCGA-E3-A3E3, project TCGA-THCA (Thyroid Carcinoma), tissue source site Roswell Park, specimen TCGA-E3-A3E3-01A (Primary Tumor).

[page 1 of 2]
Surgery Date:

SPECIMENS:

- A. RIGHT THYROID LOBECTOMY
- B. LEFT THYROID LOBE

SPECIMEN(S):

- A. RIGHT THYROID LOBECTOMY
- B. LEFT THYROID LOBE

DIAGNOSIS:

- A. THYROID, RIGHT LOBECTOMY:
- PAPILLARY THYROID CARCINOMA (2.8 CM), CONFINED TO THE GLAND
- ONE BENIGN LYMPH NODE (0/1) AND PARATHYROID GLAND

- B. THYROID, LEFT LOBECTOMY:
- BENIGN THYROID PARENCHYMA

1CD-0-3

Carcinoma, papillary, thyroid 8260/3
Site: Thyroid, NOS C73.9 10/26/11

SYNOPTIC REPORT - THYROID GLAND

Specimens Involved

Specimens: A: RIGHT THYROID LOBECTOMY

B: LEFT THYROID LOBE

Specimen Type: Right Lobe

Left Lobe

Tumor Site: Right lobe

Tumor Focality: Multifocal

Tumor Size (largest nodule): Greatest dimension: 2.8cm

Additional dimensions: 1.7cm x 1.5cm

WHO CLASSIFICATION

Papillary carcinoma 8260/3

Margins: Margins uninvolved by carcinoma

Distance of invasive carcinoma to closest margin: 0.1cm

Vascular Invasion: Absent

Lymph Node: Not performed

Pathological Staging (pTNM): pT 2 N x M x

Pathological staging is based on the AJCC Cancer Staging Manual, 7th Edition

GROSS DESCRIPTION:

A. RIGHT THYROID LOBECTOMY

Received fresh labeled with the patient's identification and "right thyroid lobectomy" is an oriented 12-g lobe of thyroid measuring 4.4 x 3.2 x 2.4 cm with a suture designating the superior pole. Capsule is nodular, red, and intact; the anterior capsule is inked blue and the posterior capsule-black. On sectioning, there is a well-circumscribed tan papillary nodule, 2.8 x 1.7 x 1.5 cm which extends to the capsule. Tissue is procured; submitted entirely:

A1: superior pole

A2-A9: cross-section is submitted from superior to inferior (4-5, 6-7, 8-9: bisected sections)

A10-A12: inferior pole, perpendicular sections

B. LEFT THYROID LOBE

Received fresh labeled with the patient's identification and "left thyroid lobe" is an oriented 4-g lobe of thyroid measuring 3.8 x 2.4 x 0.5 cm with a suture designating the superior pole. Capsule is nodular, red, and intact; the anterior capsule is inked blue, and the posterior-black. On sectioning, there is a red-brown parenchyma; no masses or lesions are identified. Submitted entirely from superior to inferior in cassettes B1-B6.

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Thyroid nodule

[page 2 of 2]
Microscopic/Diagnostic Dictation: ,
Final Review: , M.D., PATHOLOGIST ,
Final: , M.D., PATHOLOGIST

bw 10/26/11		

Source: NCI Genomic Data Commons file 042059d4-830f-4735-a39e-50ad50153152 (TCGA-E3-A3E3.E1776842-75CE-42E0-B424-E2F95ECED18E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).